TCGA case TCGA-RQ-AAAT — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4dd86ebd-ef16-4b2b-9ea0-5d1d7afef257

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Primary diffuse large B-cell lymphoma of the CNS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C71.6; Tissue or organ of origin: Cerebellum, NOS; Site of resection or biopsy: Cerebellum, NOS; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,178 days); Year of diagnosis: 2013; AJCC staging edition: 7th; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 17 days; Max tumor bulk site: Brain; Sites of involvement: Lymph node, NOS / Brain, NOS.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Consistent pathology review: Yes; Greatest tumor dimension: 1.8 cm; Measurement unit: Centimeters.

Follow-up (2 entries)
- Days to follow up: 17 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive.
- CD10 (IHC): Positive.
- CD20 (IHC): Positive.
- CD30 (IHC): Negative.
- IRF4 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68.2 kg; Height: 162.5 cm; BMI: 25.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RQ-AAAT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-RQ-AAAT-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-RQ-AAAT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RQ-AAAT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Primary DLBCL of the CNS; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 1; Maximum tumor bulk anatomic site: Posterior Fossa.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed: Mib 1 positive percent range: 76 - 100%.
- Follow-up form: Lost to follow-up: Yes.
- Follow-up form, New tumor event: Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 17 days; disease-specific survival: no event (censored), 17 days; disease-free interval: no event (censored), 17 days; progression-free interval: no event (censored), 17 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RQ-AAAT-01A-11D-A38W-01): tumor purity 0.7, ploidy 3.74, whole-genome doublings 1.
